Gene-level copy-number profile of tumor specimen HCM-STAN-0846-C20-01D from HCMI case HCM-STAN-0846-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 65.5 years (23,938 days).
Specimen HCM-STAN-0846-C20-01D: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 24c2e568-1daa-479d-a3fa-c28f5a604ebe.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-0846-C20-11D (ffpe scrolls); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,280 have no estimate.
https://portal.gdc.cancer.gov/files/882b1b9f-fa62-45de-963f-b5eea00ab898

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 1,530; copy number 2: 25,379; copy number 3: 21,573; copy number 4: 7,352; copy number 5: 1,998; copy number 6: 330; copy number 7: 135; copy number 8: 29; copy number 11: 2; copy number 12: 2.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–36,081, 6 genes: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A.
- chr1:160,446–195,411, 4 genes: AL627309.4, FO538757.1, WASH9P, MIR6859-2.
- chr2:130,680,050–130,691,691, 2 genes (within-gene range 0–3): CYP4F30P, AC140481.3.
- chr2:161,281,902–161,282,618, 1 gene (within-gene range 0–2): AC009299.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,681 genes in 125 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:257,864–522,928, 10 genes, copy number 6 (within-gene range 0–6): AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:725,885–778,626, 3 genes, copy number 5 (within-gene range 3–5): AL669831.1, RNU6-1199P, AL669831.2.
- chr1:114,089,291–114,355,178, 4 genes, copy number 5–7: SYT6, AL121999.1, MRPL57P1, AL035410.2.
- chr1:115,976,513–121,580,524, 129 genes, copy number 5 (broad region; genes not listed).
- chr1:159,780,932–159,837,492, 3 genes, copy number 5–7 (within-gene range 3–7): DUSP23, FCRL6, SLAMF8.
- chr2:28,384,409–28,426,719, 4 genes, copy number 5: FLJ31356, FOSL2, AC104695.3, AC104695.2.
- chr5:58,198–693,352, 27 genes, copy number 5: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1.
- chr5:892,884–981,300, 4 genes, copy number 5–7: TRIP13, AC122719.3, AC122719.1, AC122719.2.
- chr5:1,008,802–1,523,962, 16 genes, copy number 5: NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075.
- chr5:1,598,920–3,181,487, 26 genes, copy number 5–6: AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377.
- chr5:5,069,192–5,320,304, 5 genes, copy number 5: LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1.
- chr5:6,310,441–6,600,288, 5 genes, copy number 5–6 (within-gene range 4–6): LINC02145, MED10, UBE2QL1, AC027334.1, LINC01018.
- chr5:6,633,427–6,833,120, 5 genes, copy number 5–6: SRD5A1, LINC02102, TENT4A, LINC02236, AC122710.2.
- chr5:7,373,115–7,980,304, 8 genes, copy number 5: LINC02142, ADCY2, AC093305.1, C5orf49, MTRR, FASTKD3, AC025174.1, RNU1-76P.
- chr5:44,698,431–44,828,592, 6 genes, copy number 5: AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2.
- chr5:50,858,760–51,665,048, 15 genes, copy number 5: AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC022433.1, AC091860.2.
- chr6:31,268,749–31,301,642, 5 genes, copy number 5: HLA-C, USP8P1, RPL3P2, WASF5P, LINC02571.
- chr6:39,039,603–39,934,551, 15 genes, copy number 5–7: AL035690.1, GLP1R, SAYSD1, ANKRD18EP, KCNK5, KCNK17, KCNK16, KIF6, AL136087.1, E2F4P1, RNU1-54P, DAAM2, AL592158.1, DAAM2-AS1, MOCS1.
- chr7:37,032–5,233,840, 108 genes, copy number 5 (broad region; genes not listed).
- chr7:6,329,411–18,027,846, 152 genes, copy number 5 (broad region; genes not listed).
- chr7:20,134,655–22,357,154, 26 genes, copy number 5 (within-gene range 3–5): MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1, EEF1A1P27, AC002486.2, ABCB5, AC002486.1, SP8, RPL23P8, LINC01162, RPS26P30, AC080068.1, RN7SL542P, ASS1P11, RNU1-15P, AC005094.1, SP4, MIR1183, DNAH11, CDCA7L, RAPGEF5, RNA5SP227.
- chr7:153,887,097–156,640,654, 41 genes, copy number 5–7 (within-gene range 4–7): DPP6, AC005588.1, AC006019.3, AC006019.1, AC006019.2, AC024730.1, AC073336.1, PAXIP1-AS2, PAXIP1, AC093726.1, AC093726.2, PAXIP1-AS1, HTR5A-AS1, HTR5A, AC093726.3, AC092628.2, AC092628.1, RN7SKP280, AC099552.1, AC099552.3, AC099552.4, AC099552.2, AC144652.1, INSIG1, BLACE, AC008060.1, AC008060.4, AC008060.5, AC008060.3, EN2, CNPY1, AC009403.2, AC008060.2, AC009403.1, RBM33, SHH, AC021218.1, Y_RNA, AC093813.1, LINC01006, LINC00244.
- chr7:157,739,010–158,031,128, 5 genes, copy number 5 (within-gene range 5–6): AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1.
- chr8:61,500,556–61,714,859, 4 genes, copy number 5 (within-gene range 4–5): ASPH, KRT8P3, RN7SKP97, MIR4470.
- chr8:141,968,091–145,066,685, 168 genes, copy number 5 (within-gene range 5–7) (broad region; genes not listed).
- chr9:64,439,346–64,489,786, 5 genes, copy number 6–7: SNX18P9, CR769776.2, CYP4F25P, CNN2P3, GXYLT1P6.
- chr9:138,129,399–138,253,217, 6 genes, copy number 5: AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1, FAM157B.
- chr11:67,886,477–67,975,243, 7 genes, copy number 5–6: LINC02754, RNU6-46P, RPS3AP40, AC004923.1, AC004923.2, AC004923.3, OR7E1P.
- chr12:52,543,909–52,652,211, 7 genes, copy number 5: KRT71, KRT74, KRT72, KRT73-AS1, KRT73, KRT128P, KRT2.
- chr12:114,080,381–114,241,770, 4 genes, copy number 6–8: AC010183.2, HAUS8P1, GLULP5, LINC02459.
- chr12:127,598,168–127,636,488, 4 genes, copy number 5: AC025252.1, Y_RNA, AC025252.2, LINC02411.
- chr17:34,169,372–34,726,170, 14 genes, copy number 5 (within-gene range 4–5): LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1.
- chr17:41,004,481–41,047,316, 7 genes, copy number 6–7: KRTAP3-4P, KRTAP3-1, KRTAP1-5, KRTAP1-4, KRTAP1-3, KRTAP1-1, KRTAP2-1.
- chr17:45,620,328–45,835,826, 4 genes, copy number 5 (within-gene range 4–6): LINC02210, LINC02210-CRHR1, AC217774.1, AC217774.2.
- chr20:13,849,247–16,684,404, 28 genes, copy number 6: SEL1L2, RNU6-278P, MACROD2, RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1, AL079338.1, AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1.
- chr20:31,285,317–33,443,763, 87 genes, copy number 5 (broad region; genes not listed).
- chr20:36,045,618–36,894,235, 24 genes, copy number 5 (within-gene range 3–5): NORAD, AL035420.1, AL035420.3, HMGB3P2, AL035420.2, EPB41L1, AL121895.1, AL121895.2, AAR2, DLGAP4, DLGAP4-AS1, MYL9, Metazoa_SRP, TGIF2, TGIF2-RAB5IF, RAB5IF, SLA2, HNRNPA3P2, NDRG3, Y_RNA, DSN1, SOGA1, RN7SL156P, TLDC2.
- chr20:37,049,254–45,833,745, 207 genes, copy number 5–8 (broad region; genes not listed).
- chr20:45,898,621–47,188,844, 33 genes, copy number 5 (within-gene range 4–5): PLTP, AL162458.1, PCIF1, ZNF335, FTLP1, MMP9, SLC12A5-AS1, SLC12A5, NCOA5, RPL13P2, CD40, AL031687.1, CDH22, SLC35C2, AL133227.1, ELMO2, ZNF663P, AL031686.1, MKRN7P, ZNF840P, ZNF334, OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1.
- chr20:50,794,894–64,327,972, 308 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,530. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
